Gene-level copy-number profile of specimen HCM-CSHL-0868-C56-85A from HCMI case HCM-CSHL-0868-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIB; FIGO stage: Stage IIIB; Tumor grade: High Grade; Age at diagnosis: 62.3 years (22,759 days).
Specimen HCM-CSHL-0868-C56-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2503c1db-3680-4e6e-8142-c69e32317dc2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0868-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/790dcbf9-425f-40cc-a50f-e2afbb0b4dd1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 636; copy number 2: 22,519; copy number 3: 10,245; copy number 4: 18,241; copy number 5: 2,682; copy number 6: 2,949; copy number 7: 53; copy number 8: 1,052.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,674 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–2,569,888, 168 genes, copy number 5 (broad region; genes not listed).
- chr1:143,419,625–144,474,790, 44 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1.
- chr1:229,042,171–248,937,043, 434 genes, copy number 6 (broad region; genes not listed).
- chr2:38,814–37,646,698, 605 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:44,921,077–66,573,869, 350 genes, copy number 5 (broad region; genes not listed).
- chr2:162,371,407–192,776,899, 414 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:196,189,099–197,786,762, 31 genes, copy number 5: HECW2, HECW2-AS1, RN7SL820P, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr3:108,380,368–198,123,232, 1,580 genes, copy number 6–8 (broad region; genes not listed).
- chr4:49,096–689,271, 29 genes, copy number 5: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG, TMEM271, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3.
- chr5:44,300,247–50,443,248, 15 genes, copy number 5: FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1, EMB.
- chr5:170,747,047–181,342,213, 315 genes, copy number 6 (broad region; genes not listed).
- chr6:105,919–206,392, 6 genes, copy number 5: OR4F1P, CICP18, AL035696.2, AL035696.3, AL035696.4, AL035696.1.
- chr6:84,687,712–85,615,234, 14 genes, copy number 5 (within-gene range 4–5): TBX18-AS1, AL590143.1, AL109941.1, AL139806.1, AL122016.1, AL135903.1, KRT18P64, LINC02535, DUTP5, TPT1P6, NT5E, AL589666.2, SNX14, AL589666.1.
- chr6:91,390,313–94,447,179, 27 genes, copy number 6–7: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr8:94,708,952–101,669,726, 149 genes, copy number 6 (broad region; genes not listed).
- chr8:142,567,260–142,916,506, 22 genes, copy number 5 (within-gene range 3–5): MROH4P, ARC, AP006547.1, AC108002.2, JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1.
- chr8:142,910,559–143,160,711, 9 genes, copy number 5: CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L, LY6H.
- chr8:143,267,433–143,583,304, 19 genes, copy number 5 (within-gene range 4–5): GLI4, MINCR, TOP1MT, RNU6-220P, RHPN1-AS1, RHPN1, AC105118.1, MAFA-AS1, MAFA, ZC3H3, AC067930.9, AC067930.3, RN7SKP175, GSDMD, MROH6, AC067930.4, NAPRT, AC067930.5, AC067930.1.
- chr8:143,790,920–143,878,467, 9 genes, copy number 5: SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1.
- chr8:143,977,153–145,066,685, 76 genes, copy number 5 (broad region; genes not listed).
- chr9:61,190,003–61,666,386, 12 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr10:14,061–43,409,166, 684 genes, copy number 5 (broad region; genes not listed).
- chr11:112,967–207,428, 8 genes, copy number 6 (within-gene range 4–6): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3.
- chr11:73,214,998–87,330,052, 285 genes, copy number 6 (broad region; genes not listed).
- chr11:95,976,598–97,086,682, 12 genes, copy number 6 (within-gene range 4–6): MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1.
- chr11:134,945,118–135,075,908, 4 genes, copy number 5: AP003062.2, LINC02697, AP003062.1, LINC02684.
- chr12:15,620,134–16,277,685, 8 genes, copy number 5: EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5.
- chr12:76,025,447–76,880,352, 22 genes, copy number 5–7: PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.
- chr14:18,333,726–20,230,346, 100 genes, copy number 5–6 (broad region; genes not listed).
- chr14:22,304,054–22,497,718, 36 genes, copy number 5–7: TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:32,934,396–34,462,774, 7 genes, copy number 5: NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA.
- chr14:38,738,155–38,987,383, 4 genes, copy number 5: LINC00639, AL132994.1, AL132994.2, Y_RNA.
- chr17:45,506,741–45,551,537, 4 genes, copy number 8: LRRC37A4P, Metazoa_SRP, AC091132.3, AC091132.1.
- chr17:74,670,077–74,748,912, 5 genes, copy number 5 (within-gene range 4–5): AC064805.2, RAB37, CD300LF, AC016888.1, MIR3615.
- chr17:76,136,333–76,711,016, 35 genes, copy number 5: FOXJ1, RNF157-AS1, RNF157, ATP5MGP6, ATF4P3, UBALD2, QRICH2, PRPSAP1, Y_RNA, RNU6-24P, AC090699.1, SPHK1, UBE2O, RPL7P49, AANAT, RHBDF2, CYGB, PRCD, AC015802.4, AC015802.3, AC015802.5, SNHG16, SNORD1C, SNORD1B, SNORD1A, AC015802.6, ST6GALNAC2, AC015802.1, AC015802.2, ST6GALNAC1, RNU6-227P, AC005837.1, MXRA7, RNY4P36, AC005837.4.
- chr17:76,799,044–78,187,233, 41 genes, copy number 5: LINC02080, LINC00868, MGAT5B, AC016168.2, AC016168.1, AC016168.3, Metazoa_SRP, SNHG20, SEC14L1, SCARNA16, MIR6516, RNU4-47P, CYCSP40, SEPTIN9-DT, AC068594.1, SEPTIN9, AC111182.1, AC111182.2, MIR4316, Y_RNA, AC111170.3, AC111170.2, AC111170.1, AC021683.3, AC021683.2, AC021683.6, AC021683.1, AC021683.4, LINC01987, LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2, TK1.
- chr17:78,248,193–81,961,840, 156 genes, copy number 5 (broad region; genes not listed).
- chr17:81,976,807–83,240,804, 64 genes, copy number 5–6 (broad region; genes not listed).
- chr19:49,422,419–58,605,223, 715 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–3,410,036, 111 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 244. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
